Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A39P, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A39P-01A (Primary Tumor).

hw 9/14/11

FINAL DIAGNOSIS -----

1) THYROID (TOTAL THYROIDECTOMY):

SPECIMEN TYPE:

Total thyroidectomy

ICD-O-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid NOS C73.9

TUMOR SITE:

Left lobe

HISTOLOGIC TYPE:

Papillary carcinoma

hw
9/14/11

TUMOR SIZE:

Greatest dimension 5.3 cm

FOCALITY:

Unifocal

LYMPH NODES:

Two (2) associated lymph nodes are negative for tumor

EXTENT OF INVASION

PRIMARY TUMOR:

pT3: Tumor >4 cm, with multiple foci of extrathyroidal extension

REGIONAL LYMPH NODES:

pNO: No regional lymph node metastasis

DISTANT METASTASIS:

pMx: Cannot be assessed

MARGINS:

Involved by invasive carcinoma, Specify margin: left lobe, superior, mid

VENOUS/LYMPHATIC INVASION:

Present

ADDITIONAL PATHOLOGIC FINDINGS:

Nodular hyperplasia

SEE NOTE.

NOTE: Dr. has seen representative slides (A-D) of this case and concurs.

Source: NCI Genomic Data Commons file edfcbb82-8175-4949-8d09-c315ee07bad9 (TCGA-ET-A39P.B37A8A96-8B16-45CD-BDC9-57C00FE33F65.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).